Somatic mutation profile of tumor specimen TCGA-06-0126-01A (aliquot TCGA-06-0126-01A-01D-1490-08) from TCGA case TCGA-06-0126, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 86.6 years (31,627 days).
Specimen TCGA-06-0126-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5db12b9-5a42-49c3-82f0-ef4f8f3bf5a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0126-10A (Blood Derived Normal), aliquot TCGA-06-0126-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/444e14e0-a6fd-494e-bbcd-22dc1c676158

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG1 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 80/249 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs757151743, COSV59207269; called by muse, mutect2, varscan2
- ADRA2C | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57467736; called by muse, mutect2, varscan2
- ANO2 | c.550C>T p.R184W (on ENST00000356134 / NM_001278597.3; = p.R188W on NM_001278596.3) | Missense Mutation (SNP) | VAF 114/356 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767675843, COSV59032366; called by muse, varscan2
- C8A | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.208); catalogued as rs775054168, COSV63485447; called by muse, mutect2, varscan2
- CCDC170 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1316790258, COSV53343187; called by muse, mutect2, varscan2
- CHD9 | c.4090A>G p.I1364V | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs1318345762, COSV54613067; called by muse, mutect2, varscan2
- CNTN4 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61876209; called by muse, mutect2, varscan2
- COL1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746504964, COSV51956931; called by muse, mutect2, varscan2
- DAO | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.021); catalogued as COSV57321584; called by muse, mutect2, varscan2
- DNAH5 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238318; called by muse, mutect2, varscan2
- FGB | c.1220C>T p.T407M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM153763, COSV57417515; called by muse, mutect2, varscan2
- HMBS | c.614T>G p.I205S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV53829322; called by muse, mutect2, varscan2
- KLHL7 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59162737; called by muse, mutect2, varscan2
- LGSN | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.495); catalogued as COSV65727749; called by muse, mutect2, varscan2
- LUM | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs777345268, COSV57127390; called by muse, mutect2, varscan2
- MROH2B | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.964); catalogued as rs746281100, COSV68186680; called by muse, mutect2, varscan2
- MRPL32 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV56239753; called by muse, mutect2, varscan2
- MUC16 | c.6688T>C p.S2230P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV67478768; called by muse, mutect2, varscan2
- NECTIN4 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.852); catalogued as COSV63513314; called by muse, mutect2, varscan2
- NEDD4 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs753990774, COSV59063895; called by muse, mutect2, varscan2
- OR2Y1 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57137378; called by muse, mutect2, varscan2
- OR4N5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 132/324 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs202234247, COSV61320453; called by muse, varscan2
- OR7G2 | c.895T>A p.Y299N | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59688440; called by muse, mutect2, varscan2
- PCDH9 | c.2474T>A p.V825E | Missense Mutation (SNP) | VAF 101/256 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV60568363; called by muse, mutect2, varscan2
- PLCG2 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV63868628; called by muse, mutect2, varscan2
- RAG2 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57558626; called by muse, mutect2, varscan2
- RAPGEF2 | c.734T>G p.V245G | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV52430732; called by muse, mutect2, varscan2
- RGS1 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV66504981, COSV66505876; called by muse, mutect2, varscan2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SMC3 | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV62421116; called by muse, mutect2, varscan2
- SNRNP48 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60940175; called by muse, mutect2, varscan2
- SREBF2 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769759580, COSV63331856; called by muse, mutect2, varscan2
- SYDE2 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs561704514, COSV52316580; called by muse, mutect2, varscan2
- TEK | c.231T>A p.D77E | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV66230631; called by muse, mutect2, varscan2
- TEX2 | c.1725G>T p.E575D | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.194); catalogued as COSV51983234; called by muse, mutect2, varscan2
- TGFBR1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 176/424 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.561); catalogued as COSV66626256; called by muse, mutect2, varscan2
- TNFRSF1B | c.664A>C p.T222P | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV66164683; called by muse, mutect2, varscan2
- TTN | c.58386G>T p.M19462I (on ENST00000591111; = p.M12038I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | PolyPhen benign (0.003); catalogued as COSV60070984, COSV60184094; called by muse, mutect2, varscan2
- UGT2B28 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 121/310 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59431034; called by muse, mutect2, varscan2
- ZNF135 | c.1292T>G p.I431S (on ENST00000313434 / NM_001289401.2; = p.I443S on NM_003436.4) | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1315843392, COSV57883846; called by muse, mutect2, varscan2
- C8orf76 | c.612_614del p.F205del | In Frame Del (DEL) | VAF 77/186 reads (41%) | called by pindel, varscan2
- LPAR3 | c.662_675del p.S221Wfs*107 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- RYR3 | c.11823dup p.E3942Rfs*18 (on ENST00000389232; = p.E3943Rfs*18 on NM_001036.6) | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- ABCC5 | c.3276G>A p.T1092= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs745426596, COSV55593204; called by muse, mutect2, varscan2
- CDCA4 | c.678C>T p.S226= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs534887423, COSV60315503; called by muse, mutect2, varscan2
- CDK20 | c.480C>T p.Y160= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs766517987, COSV57483325; called by muse, mutect2, varscan2
- EIF2AK4 | c.2541G>A p.R847= | Silent (SNP) | VAF 75/236 reads (32%) | catalogued as COSV55470787; called by muse, mutect2, varscan2
- ETV3L | c.417C>A p.S139= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as COSV71901154; called by muse, mutect2, varscan2
- FCGBP | c.6681G>A p.G2227= | Silent (SNP) | VAF 54/483 reads (11%) | called by muse, mutect2, varscan2
- GALNT17 | c.939C>T p.A313= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs755966198, COSV61173344; called by muse, mutect2, varscan2
- GRIA2 | c.651C>T p.N217= | Silent (SNP) | VAF 56/177 reads (32%) | catalogued as rs774807805, COSV52397297; called by muse, mutect2, varscan2
- GRM3 | c.1722C>T p.D574= | Silent (SNP) | VAF 90/252 reads (36%) | catalogued as rs372193050; called by muse, mutect2, varscan2
- ORM2 | c.151C>A p.R51= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV52280051; called by muse, mutect2, varscan2
- PPME1 | c.1158T>C p.C386= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV60297351; called by muse, mutect2, varscan2
- SORBS2 | c.1521C>T p.P507= | Silent (SNP) | VAF 64/163 reads (39%) | catalogued as COSV53006878; called by muse, mutect2, varscan2
- THNSL1 | c.993G>A p.R331= | Silent (SNP) | VAF 51/73 reads (70%) | catalogued as COSV100896257, COSV64479587; called by muse, mutect2, varscan2
- THRAP3 | c.516T>C p.S172= | Silent (SNP) | VAF 171/442 reads (39%) | catalogued as COSV63568778; called by muse, mutect2, varscan2
- TMEM59L | c.966G>A p.P322= | Silent (SNP) | VAF 60/189 reads (32%) | catalogued as rs768557209, COSV53242806; called by muse, mutect2, varscan2
